Somatic mutation profile of tumor specimen TCGA-BS-A0V8-01A (aliquot TCGA-BS-A0V8-01A-11D-A122-09) from TCGA case TCGA-BS-A0V8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.4 years (24,981 days).
Specimen TCGA-BS-A0V8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdbd4a2d-906d-4083-a403-cbc6184e3f95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0V8-10A (Blood Derived Normal), aliquot TCGA-BS-A0V8-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7c56276-c398-4e56-87f4-49e103696034

The open-access MAF lists 92 somatic variants for this specimen: 71 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 20, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72658104, CM042013, COSV51964799; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 186/514 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781255, CM128490, COSV64289445, COSV64291964; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 195/483 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 111/192 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.4451A>C p.E1484A | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as COSV62356354; called by muse, mutect2, varscan2
- ANO10 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV52735500; called by muse, mutect2, varscan2
- BIRC2 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV57162865; called by muse, mutect2, varscan2
- C20orf96 | c.306+1G>T p.X102_splice (on ENST00000360321 / NM_153269.3; = p.X101_splice on NM_080571.1) | Splice Site (SNP) | VAF 52/350 reads (15%) | catalogued as COSV64404430; called by muse, mutect2, varscan2
- C20orf96 | c.306G>C p.K102N (on ENST00000360321 / NM_153269.3; = p.K101N on NM_080571.1) | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV64404440; called by muse, mutect2, varscan2
- CBL | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 37/231 reads (16%) | catalogued as rs200341293, CM1314298, COSV50630874, COSV50653789; called by muse, mutect2, varscan2
- CRISPLD1 | c.969A>T p.K323N | Missense Mutation (SNP) | VAF 139/697 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV51552493; called by muse, mutect2, varscan2
- CTNNB1 | c.509A>T p.K170M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV62716643; called by muse, mutect2, varscan2
- EDRF1 | c.2420_2421del p.S807Cfs*2 (on ENST00000356792 / NM_001202438.2; = p.S773Cfs*2 on NM_015608.2) | Frame Shift Del (DEL) | VAF 86/616 reads (14%) | catalogued as rs1564744334; called by pindel, varscan2
- FGFR1 | c.2033C>G p.T678S (on ENST00000447712 / NM_023110.3; = p.T676S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/191 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58342893; called by muse, mutect2, varscan2
- FUCA1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1005744482, COSV65699323; called by muse, mutect2, varscan2
- HBB | c.103G>C p.V35L | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1141387, CM033781, CM800011, HM971912, COSV100092842; called by muse, mutect2, varscan2
- HP1BP3 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56564415; called by muse, mutect2, varscan2
- HTR1F | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60390810; called by muse, mutect2, varscan2
- IQCF1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778155817, COSV58823457; called by muse, mutect2, varscan2
- IRAK1 | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64113077; called by muse, mutect2, varscan2
- KRTAP26-1 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100860514; called by muse, mutect2
- LETMD1 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 111/576 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50396891; called by muse, varscan2
- LRRC7 | c.1186G>A p.E396K (on ENST00000651989 / NM_001370785.2; = p.E363K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/313 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV50603388; called by muse, mutect2, varscan2
- MME | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 75/279 reads (27%) | catalogued as rs150836510; called by muse, mutect2, varscan2
- MUC5B | c.13127C>G p.T4376S | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.078); catalogued as rs943228511, COSV71594879; called by muse, mutect2, varscan2
- MYO3B | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs532693197, COSV58715132; called by muse, mutect2, varscan2
- NKTR | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as rs764754257, COSV51774775; called by muse, mutect2, varscan2
- NYNRIN | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs554700851, COSV66844680; called by muse, mutect2, varscan2
- OBSCN | c.5224C>G p.L1742V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.056); catalogued as COSV52820606; called by muse, varscan2
- OBSCN | c.17293G>A p.D5765N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772459899, COSV52738843; called by muse, mutect2, varscan2
- OR10G8 | c.227T>G p.V76G | Missense Mutation (SNP) | VAF 84/333 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV70909313; called by muse, mutect2, varscan2
- OR2A2 | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV68872444; called by muse, mutect2, varscan2
- OR4K15 | c.646A>T p.T216S (on ENST00000305051; = p.T192S on NM_001005486.1) | Missense Mutation (SNP) | VAF 182/379 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV59303169; called by muse, mutect2, varscan2
- PCDHB14 | c.1489C>G p.H497D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.099); catalogued as COSV53390871; called by muse, mutect2, varscan2
- PICALM | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 199/438 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs748465366, COSV62673639; called by muse, mutect2, varscan2
- PIGA | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100363560; called by muse, mutect2
- PIKFYVE | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1481613135, COSV52248171; called by muse, mutect2, varscan2
- PNLIP | c.930+1G>A p.X310_splice | Splice Site (SNP) | VAF 62/359 reads (17%) | catalogued as rs1489238049, COSV65041832; called by muse, mutect2, varscan2
- POGLUT2 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 19/449 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV101050829; called by muse, mutect2
- PRDM9 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as COSV57012148; called by muse, mutect2, varscan2
- PRG3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as COSV54664535; called by muse, mutect2, varscan2
- PRKCQ | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV54117893; called by muse, mutect2, varscan2
- PTCD3 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 99/605 reads (16%) | catalogued as rs749650341, COSV54480590; called by muse, mutect2, varscan2
- QSER1 | c.3106A>G p.M1036V (on ENST00000399302; = p.M1165V on NM_001076786.3) | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs769815493, COSV67901643; called by muse, mutect2, varscan2
- RANBP2 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51707396; called by muse, mutect2, varscan2
- RYR2 | c.3263T>G p.F1088C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV63709595; called by muse, mutect2, varscan2
- SASH1 | c.1117_1124del p.F373Pfs*37 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as COSV66565063; called by mutect2, pindel, varscan2
- SBF1 | c.2882T>C p.L961P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62370149; called by muse, mutect2, varscan2
- SLC16A5 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886562459, COSV61676760; called by muse, mutect2, varscan2
- SLC7A3 | c.1650G>C p.M550I | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53229096; called by muse, mutect2, varscan2
- SLC9A3R1 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 129/189 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs754888522, COSV52854828; called by muse, mutect2, varscan2
- SMARCA4 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1436490540, COSV60807076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX13 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377458455; called by muse, mutect2, varscan2
- SPOCK3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 19/662 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV100694204; called by muse, mutect2
- SRGAP2 | c.2233G>C p.E745Q (on ENST00000624873 / NM_001170637.4; = p.E746Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55342263; called by muse, mutect2, varscan2
- STAT4 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs780829180, COSV61828946, COSV61831938; called by muse, varscan2
- STATH | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 129/465 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55894188; called by muse, mutect2, varscan2
- SYT5 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62831204; called by muse, mutect2, varscan2
- TAF1L | c.2281G>C p.A761P | Missense Mutation (SNP) | VAF 171/572 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54267841, COSV54271930; called by muse, mutect2, varscan2
- TTN | c.69926G>C p.R23309T (on ENST00000591111; = p.R15885T on NM_003319.4) | Missense Mutation (SNP) | VAF 46/238 reads (19%) | PolyPhen benign (0.167); catalogued as COSV60298162; called by muse, mutect2, varscan2
- USP4 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 163/1158 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55540151; called by muse, mutect2, varscan2
- ZNF99 | c.1868G>C p.C623S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101233803, COSV101233918; called by muse, mutect2
- ARID1A | c.2750del p.N917Ifs*2 | Frame Shift Del (DEL) | VAF 89/170 reads (52%) | called by mutect2, pindel, varscan2
- CACNA1D | c.1825del p.I609Sfs*16 (on ENST00000350061 / NM_001128840.3; = p.I629Sfs*16 on NM_000720.4) | Frame Shift Del (DEL) | VAF 102/549 reads (19%) | called by mutect2, pindel, varscan2
- CDH8 | c.286del p.I96Sfs*16 | Frame Shift Del (DEL) | VAF 47/215 reads (22%) | called by mutect2, pindel, varscan2
- CLEC4E | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPXCR1 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DDX5 | c.1366_1381del p.L456Vfs*29 | Frame Shift Del (DEL) | VAF 191/321 reads (60%) | called by mutect2, pindel, varscan2
- EYA2 | c.530_531del p.Y177Lfs*45 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- GPR158 | c.3199G>T p.D1067Y | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2
- IL13RA1 | c.1010del p.X337_splice | Splice Site (DEL) | VAF 243/634 reads (38%) | called by mutect2, pindel, varscan2
- AIFM1 | c.1680C>T p.Y560= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs776215622, COSV54855938; called by muse, mutect2
- CHD1 | c.3189A>G p.E1063= | Silent (SNP) | VAF 282/628 reads (45%) | catalogued as rs1199057550, COSV52344148; called by muse, mutect2, varscan2
- COL6A5 | c.7551C>T p.N2517= (on ENST00000312481; = p.N2513= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/406 reads (17%) | catalogued as rs201292581, COSV55194672; called by muse, mutect2, varscan2
- CPXM2 | c.687G>T p.V229= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as COSV53869737; called by muse, mutect2, varscan2
- CSMD1 | c.5982T>C p.S1994= (on ENST00000520002; = p.S1993= on NM_033225.6) | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as COSV100154497, COSV59358697; called by muse, mutect2
- EZHIP | c.1233C>G p.P411= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV57957431; called by muse, mutect2, varscan2
- F8 | c.4506A>G p.P1502= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- FOXP1 | c.1905C>G p.V635= | Silent (SNP) | VAF 68/378 reads (18%) | catalogued as COSV59552712; called by muse, mutect2, varscan2
- GABRA4 | c.1248T>G p.V416= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV51934071; called by muse, mutect2, varscan2
- IGSF10 | c.1719C>T p.V573= | Silent (SNP) | VAF 85/288 reads (30%) | catalogued as rs193019990, COSV56786890; called by muse, mutect2, varscan2
- ITIH5 | c.1278C>T p.A426= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as rs770236790, COSV53672639, COSV99903206; called by muse, mutect2, varscan2
- MED14 | c.4200C>T p.D1400= | Silent (SNP) | VAF 64/340 reads (19%) | catalogued as rs1372696650, COSV61358343; called by muse, mutect2, varscan2
- PBDC1 | c.612A>C p.G204= | Silent (SNP) | VAF 36/823 reads (4%) | catalogued as COSV100972882; called by muse, mutect2
- PDE3A | c.1578C>T p.C526= | Silent (SNP) | VAF 47/179 reads (26%) | catalogued as COSV62981541; called by muse, mutect2, varscan2
- PTPN14 | c.1584G>A p.P528= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs564427221, COSV65283431, COSV65287706; called by muse, mutect2, varscan2
- RPS6KA6 | c.1923A>G p.K641= | Silent (SNP) | VAF 102/354 reads (29%) | catalogued as COSV53125798; called by muse, mutect2, varscan2
- SLC43A2 | c.1356C>G p.L452= | Silent (SNP) | VAF 41/61 reads (67%) | catalogued as COSV56771008; called by muse, mutect2, varscan2
- TRPC7 | c.516G>A p.A172= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs759878900, COSV61458518; called by muse, mutect2, varscan2
- XKR7 | c.1242G>A p.S414= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1197757286, COSV73813331; called by muse, mutect2, varscan2
- ZNF665 | c.1194C>T p.C398= (on ENST00000600412; = p.C463= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs769149028, COSV67217192; called by muse, mutect2, varscan2
- MIR124-2 | n.69C>T | RNA (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
